Somatic mutation profile of tumor specimen TCGA-EJ-A65M-01A (aliquot TCGA-EJ-A65M-01A-11D-A29Q-08) from TCGA case TCGA-EJ-A65M, project TCGA-PRAD (Prostate Adenocarcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Prostate gland; Age at diagnosis: 65.1 years (23,767 days).
Specimen TCGA-EJ-A65M-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 8d1dd193-3c36-4f7f-8f4d-eb052781d439.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-EJ-A65M-10A (Blood Derived Normal), aliquot TCGA-EJ-A65M-10A-01D-A29Q-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/1a754645-dd5a-4a58-abd7-69dca94628fe

The open-access MAF lists 34 somatic variants for this specimen: 24 protein-altering or splice-affecting, 8 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 19, Silent 8, Nonsense Mutation 3, Intron 2, Splice Region 1, Frame Shift Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- SPOP | c.260A>G p.Y87C | Missense Mutation (SNP) | VAF 22/84 reads (26%) | hotspot (GDC flag); SIFT tolerated (0.11); PolyPhen possibly damaging (0.539); catalogued as rs1057519971, COSV100753468, COSV61652670, COSV61653014; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- ALKBH4 | c.269G>A p.R90Q | Missense Mutation (SNP) | VAF 49/237 reads (21%) | SIFT tolerated (0.71); PolyPhen benign (0); catalogued as rs751229861, COSV52961500; called by muse, mutect2, varscan2
- CACNA1E | c.4187G>A p.R1396H | Missense Mutation (SNP) | VAF 29/131 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs776066299, COSV62407591; called by muse, mutect2, varscan2
- CNGA4 | c.350T>G p.L117W | Missense Mutation (SNP) | VAF 103/355 reads (29%) | SIFT tolerated (0.18); PolyPhen benign (0.118); catalogued as COSV66006530; called by muse, mutect2, varscan2
- CRTC1 | c.578del p.S193* | Frame Shift Del (DEL) | VAF 92/438 reads (21%) | catalogued as COSV100118989; called by mutect2, pindel, varscan2
- DLGAP2 | c.2288G>A p.R763Q | Missense Mutation (SNP) | VAF 3/33 reads (9%) | SIFT tolerated (0.16); PolyPhen probably damaging (0.988); catalogued as rs1189899592, COSV70097308; called by muse, mutect2
- DST | c.18089G>A p.W6030* (on ENST00000361203 / NM_001374722.1; = p.W3727* on NM_015548.5) | Nonsense Mutation (SNP) | VAF 25/95 reads (26%) | catalogued as COSV54996110, COSV55028725; called by muse, mutect2, varscan2
- DST | c.7662G>C p.W2554C | Missense Mutation (SNP) | VAF 6/33 reads (18%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.973); catalogued as COSV55028750; called by muse, mutect2
- FCGR2B | c.430G>T p.E144* | Nonsense Mutation (SNP) | VAF 5/37 reads (14%) | catalogued as COSV99374902; called by muse, mutect2, varscan2
- INSRR | c.41C>T p.P14L | Missense Mutation (SNP) | VAF 18/107 reads (17%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV62327290; called by muse, mutect2, varscan2
- KCNS1 | c.329T>A p.F110Y | Missense Mutation (SNP) | VAF 5/19 reads (26%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.925); catalogued as COSV60260574; called by muse, mutect2
- KLB | c.2471A>T p.N824I | Missense Mutation (SNP) | VAF 10/102 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV57303501; called by muse, mutect2
- KLHDC9 | c.1003G>A p.D335N | Missense Mutation (SNP) | VAF 46/180 reads (26%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.994); catalogued as COSV63510175; called by muse, mutect2, varscan2
- LAMC1 | c.1520C>G p.A507G | Missense Mutation (SNP) | VAF 15/125 reads (12%) | SIFT deleterious (0); PolyPhen possibly damaging (0.875); catalogued as COSV51156872; called by muse, mutect2, varscan2
- LIME1 | c.656A>G p.D219G | Missense Mutation (SNP) | VAF 10/57 reads (18%) | SIFT tolerated (0.11); PolyPhen benign (0.003); catalogued as COSV55512604; called by mutect2, varscan2
- LPAR3 | c.940G>C p.E314Q | Missense Mutation (SNP) | VAF 28/114 reads (25%) | SIFT tolerated (0.55); PolyPhen benign (0); catalogued as COSV65454377; called by muse, mutect2, varscan2
- OPLAH | c.2511G>A p.P837= | Splice Region (SNP) | VAF 16/74 reads (22%) | catalogued as rs782782095, COSV70678752; called by muse, mutect2, varscan2
- PKHD1 | c.9125T>C p.I3042T | Missense Mutation (SNP) | VAF 26/107 reads (24%) | SIFT tolerated (0.08); PolyPhen benign (0.418); catalogued as COSV61887338; called by muse, mutect2, varscan2
- RAI14 | c.2510A>C p.N837T | Missense Mutation (SNP) | VAF 32/133 reads (24%) | SIFT tolerated (0.97); PolyPhen benign (0.003); catalogued as COSV54299398; called by muse, mutect2, varscan2
- RP1L1 | c.639C>A p.S213R | Missense Mutation (SNP) | VAF 14/64 reads (22%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.972); catalogued as COSV61446669; called by muse, mutect2, varscan2
- SYNE1 | c.24720G>A p.W8240* (on ENST00000367255 / NM_182961.4; = p.W8169* on NM_033071.3) | Nonsense Mutation (SNP) | VAF 10/107 reads (9%) | catalogued as COSV55043170; called by muse, mutect2
- VCAN | c.8066C>T p.T2689M | Missense Mutation (SNP) | VAF 25/147 reads (17%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.999); catalogued as rs182041589, COSV54111370; called by muse, mutect2, varscan2
- ZNF37A | c.370G>T p.G124W | Missense Mutation (SNP) | VAF 13/195 reads (7%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.817); catalogued as COSV61074587; called by muse, mutect2
- ANKRD17 | c.2275C>A p.Q759K | Missense Mutation (SNP) | VAF 3/49 reads (6%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.074); called by muse, mutect2
- ATF4 | c.93A>G p.L31= | Silent (SNP) | VAF 34/140 reads (24%) | catalogued as rs200926784, COSV57479896; called by muse, mutect2, varscan2
- GFI1 | c.967A>C p.R323= | Silent (SNP) | VAF 24/114 reads (21%) | catalogued as COSV54043322; called by muse, mutect2, varscan2
- IGKV1D-12 | c.81C>G p.T27= | Silent (SNP) | VAF 25/146 reads (17%) | called by muse, mutect2, varscan2
- JMJD1C | c.3207T>C p.D1069= | Silent (SNP) | VAF 71/244 reads (29%) | catalogued as COSV59516888; called by muse, mutect2, varscan2
- KLB | c.2472C>T p.N824= | Silent (SNP) | VAF 11/102 reads (11%) | catalogued as COSV57303514; called by muse, mutect2, varscan2
- PCDHB16 | c.1206C>A p.T402= | Silent (SNP) | VAF 22/115 reads (19%) | catalogued as COSV53367137; called by muse, mutect2, varscan2
- PLAC8 | c.306C>A p.I102= | Silent (SNP) | VAF 6/54 reads (11%) | catalogued as COSV61048003; called by muse, mutect2, varscan2
- PPP1R3D | c.657G>A p.A219= | Silent (SNP) | VAF 12/93 reads (13%) | catalogued as rs945074874, COSV62564799; called by muse, mutect2, varscan2
- LARP7 | c.1142+591C>G | Intron (SNP) | VAF 29/70 reads (41%) | catalogued as COSV100135002; called by muse, mutect2, varscan2
- MAZ | c.1280-450T>A | Intron (SNP) | VAF 14/49 reads (29%) | catalogued as COSV50716845; called by muse, mutect2, varscan2
